Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3UQ, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3UQ-01A (Primary Tumor).

[page 1 of 4]
Neck
and Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

Left lobe- papillary carcinoma.

Specimens Submitted:

- 1: Pretracheal tissue
- 2: Tissue near the left upper pole
- 3: Left paratracheal tissue (fs)
- 4: Left superior mediastinal tissue
- 5: Right paratracheal tissue
- 6: Total thyroidectomy

DIAGNOSIS:

1. Pretracheal tissue; biopsy:
- Benign fibroadipose tissue
2. Tissue near the left upper pole; biopsy:
- Benign thyroid tissue

ICD-O-3

carcinoma, papillary, tall cell

8344/3

Site: thyroid, NOS

C73.9 5-212
RD

3. Left paratracheal tissue (fs):

Part # 3

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 3
Number of lymph nodes with metastatic disease: 3
Size of the largest lymph node involved by tumor: 0.5cm.
Size of the largest metastatic focus : 0.3 cm.
Extranodal extension is not identified

Comment: Three lymph nodes are identified on the permanent section of the frozen section residue; however, only one lymph node is present on the original frozen section slide.

4. Left superior mediastinal tissue:

Part # 4

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 1
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 0.15cm.
Size of the largest metastatic focus : 0.02 cm.
Extranodal extension is not identified

5. Right paratracheal tissue:

Part # 5

[page 2 of 4]
Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 2
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 0.6cm.
Size of the largest metastatic focus : 0.2 cm.
Extranodal extension is not identified

6. Total thyroidectomy:

Part # 6

Tumor Type:

Papillary microcarcinoma with focal tall cell and columnar cell features *Tall cell $\geq 50\%$ per TSS / per*

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 0.8 cm.

Tumor Encapsulation:

None identified

Blood Vessel Invasion:

Areas suggestive but not diagnostic

Extrathyroid Extension:

Invades: perithyroidal fibroadipose tissue

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Microscopic foci present

Papillary microcarcinoma with sclerosis, cystic change and squamous metaplasia, 0.6 cm in greatest dimension
(right lobe)

Adenoma(s) (away from the carcinoma):

Not identified

Non-Neoplastic Thyroid:

No abnormalities identified

Parathyroid Glands:

Not identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result

Special Stain

Comment

[page 3 of 4]
RECUT
RECUT
RECUT

Gross Description:

1). The specimen is received in formalin, labeled "Pre-tracheal tissue" and consists of an irregular fragment tan soft tissue measuring 0.6 x 0.6 x 0.4 cm. The specimen is entirely submitted.

Summary of sections:

U-- undesignated

2). The specimen is received in formalin, labeled "Tissue near the left upper pole" and consists of an irregular fragment tan soft tissue measuring 0.3 x 0.2 x 0.1 cm. The specimen is entirely submitted.

Summary of sections:

U-- undesignated

3) The specimen is received fresh for frozen section and is labeled "left paratracheal tissue". It consists of a portion of tan soft tissue measuring 0.6 x 0.4 x 0.3 cm. The specimen is entirely submitted.

Summary of sections:

FSC-frozen section control

4) The specimen is received in formalin, labeled "Left superior mediastinal tissue", and consists of a fragment of tan soft tissue measuring 0.4 x 0.3 x 0.2 cm. The specimen is submitted entirely.

Summary of sections:

U - undesignated

5) The specimen is received in formalin, labeled "Right paratracheal tissue", and consists of a fragment of tan soft tissue measuring 0.9 x 0.7 x 0.3 cm. The specimen is submitted entirely.

Summary of sections:

U - undesignated

6) The specimen is received fresh, labeled "Total thyroidectomy", and consists of a thyroid weighing 17g. A stitch marks the left lobe of thyroid. The right lobe measures 4.3 x 2.3 x 1.8 cm, the left lobe measures 4.1 x 2.1 x 1.3 cm and the isthmus measures 2.1 x 0.5 x 0.3 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a tan firm nodule. The nodule is located in the superior pole of the left lobe, measuring 0.7 x 0.6 x 0.6 cm; and is not encapsulated. Also identified is a cystic nodule located in the middle portion of the right lobe, measuring 0.6 x 0.5 x 0.4 cm. The remaining thyroid parenchyma is red brown and beefy. Representative sections of the specimen are submitted for . The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

N - nodule in the left lobe, entirely submitted

CN - cystic nodule in the right lobe, entirely submitted

RL - remaining right lobe

LL - remaining left lobe

IS - isthmus

Summary of Sections:

Part 1: Pretracheal tissue

[page 4 of 4]
Block	Sect. Site	PCs
1	U	1

Part 2: Tissue near the left upper pole

Block	Sect. Site	PCs
1	U	1

Part 3: Left paratracheal tissue (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 4: Left superior mediastinal tissue

Block	Sect. Site	PCs
1	U	1

Part 5: Right paratracheal tissue

Block	Sect. Site	PCs
1	U	1

Part 6: Total thyroidectomy

Block	Sect. Site	PCs
2	CN	2
1	IS	2
4	LL	5
2	N	2
3	RL	4

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

3. Frozen Section Diagnosis: Left paratracheal tissue (fs): Metastatic carcinoma (1/1)
Permanent Diagnosis: See final

Source: NCI Genomic Data Commons file 45eb9c95-1eaf-476c-9127-3bab56e740f5 (TCGA-DJ-A3UQ.2F03D3BA-CD94-4EAE-8084-EBDCB3143222.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).